Somatic mutation profile of tumor specimen MMRF_1891_1_BM_CD138pos (aliquot MMRF_1891_1_BM_CD138pos_T1_KBS5U_L07243) from MMRF case MMRF_1891, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.3 years (23,845 days).
Specimen MMRF_1891_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 380a94f2-3e59-4617-a4ab-2f0b026c3d53.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1891_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1891_1_PB_Whole_C3_KBS5U_L07244; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5e59bf6-67d2-45d0-89e9-ab7c936d5e01

The open-access MAF lists 76 somatic variants for this specimen: 37 protein-altering or splice-affecting, 8 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 22, Silent 8, Intron 7, Nonsense Mutation 3, Splice Region 2, 5'Flank 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8B4 | c.3301C>T p.R1101C | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs771493565, COSV52708588; called by muse, mutect2, varscan2
- DNAH2 | c.8642G>A p.R2881H | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs144848007; called by muse, mutect2, varscan2
- DNAH9 | c.9616C>T p.R3206W | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367619575; called by muse, mutect2
- FNDC1 | c.1487C>T p.S496F | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.044); catalogued as COSV51945650; called by muse, mutect2, varscan2
- GTF3C1 | c.920C>G p.S307C | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs535852272; called by muse, mutect2, varscan2
- LRRTM4 | c.965T>G p.L322* | Nonsense Mutation (SNP) | VAF 89/177 reads (50%) | catalogued as rs1287064212; called by muse, mutect2, varscan2
- PCDHB6 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 17/403 reads (4%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.038); catalogued as rs781990091, COSV50705386; called by muse, mutect2
- PRR16 | c.185C>A p.T62N (on ENST00000407149 / NM_001300783.2; = p.T39N on NM_016644.2) | Missense Mutation (SNP) | VAF 98/231 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65398063, COSV65407606; called by muse, varscan2
- RPL11 | c.389A>G p.Y130C (on ENST00000374550 / NM_001199802.1; = p.Y131C on NM_000975.5) | Missense Mutation (SNP) | VAF 14/273 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as rs1413848818, COSV65778646; called by muse, mutect2
- SLC6A9 | c.677C>T p.T226M (on ENST00000360584 / NM_201649.4; = p.T172M on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1007434363, COSV62210763; called by muse, mutect2, varscan2
- TRPC4 | c.2572G>C p.E858Q (on ENST00000379705 / NM_016179.4; = p.E863Q on NM_003306.3) | Missense Mutation (SNP) | VAF 62/66 reads (94%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.262); catalogued as rs761506347, COSV100156232; called by muse, varscan2
- AMN | c.796G>C p.D266H | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- CYP4A11 | c.1405G>T p.V469L | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- EEF1AKNMT | c.1414G>A p.E472K (on ENST00000361735 / NM_015935.5; = p.E386K on NM_014955.3) | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- FLT4 | c.242T>C p.V81A | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FNDC1 | c.2957C>T p.S986L | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KANK2 | c.1521-1G>A p.X507_splice (on ENST00000586659 / NM_001379562.1; = p.X515_splice on NM_015493.7 and 7 other RefSeq transcripts) | Splice Site (SNP) | VAF 106/176 reads (60%) | called by muse, mutect2, varscan2
- LHX9 | c.433A>G p.M145V | Missense Mutation (SNP) | VAF 10/265 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.152); called by muse, mutect2
- LINGO3 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP4 | c.3413T>C p.V1138A | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- LRRC18 | c.212A>C p.K71T | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- MCM3 | c.1760T>A p.I587N (on ENST00000229854 / NM_001366374.2; = p.I577N on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/120 reads (55%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- MEGF10 | c.1587C>A p.C529* | Nonsense Mutation (SNP) | VAF 38/74 reads (51%) | called by muse, mutect2, varscan2
- NEDD4L | c.1662G>T p.W554C (on ENST00000400345 / NM_001144967.3; = p.W534C on NM_015277.6) | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NELL1 | c.1113G>T p.L371F | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- NUP160 | c.2080+5del | Splice Region (DEL) | VAF 91/179 reads (51%) | called by mutect2, varscan2
- PCLO | c.2839T>C p.S947P | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- RABGGTA | c.470C>G p.A157G | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- RCC2 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.013); called by muse, mutect2
- RPS6KB1 | c.1130A>T p.E377V | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- SLC7A10 | c.150C>T p.I50= | Splice Region (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- TRAF3 | c.1326C>A p.S442R | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAF3 | c.1446T>G p.Y482* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | called by muse, mutect2, varscan2
- TRHDE | c.1406T>G p.F469C | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TRPC4 | c.671G>T p.S224I | Missense Mutation (SNP) | VAF 87/91 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- YLPM1 | c.5992G>C p.D1998H | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF700 | c.2065A>G p.K689E | Missense Mutation (SNP) | VAF 129/423 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ALDH1B1 | c.1137G>A p.K379= | Silent (SNP) | VAF 13/306 reads (4%) | called by muse, mutect2
- DUSP2 | c.375G>A p.V125= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as rs1005029732; called by muse, mutect2, varscan2
- NEB | c.9957G>A p.K3319= | Silent (SNP) | VAF 64/129 reads (50%) | catalogued as COSV99424256; called by muse, mutect2, varscan2
- PRPF31 | c.1380G>A p.L460= | Silent (SNP) | VAF 8/154 reads (5%) | catalogued as rs377605774; called by muse, mutect2
- TNR | c.3609C>T p.N1203= | Silent (SNP) | VAF 72/226 reads (32%) | catalogued as rs145190320, COSV99688705, COSV99692471; called by muse, mutect2, varscan2
- TTN | c.38223G>A p.L12741= (on ENST00000591111; = p.L5317= on NM_003319.4) | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as rs751236287, COSV100605476, COSV60244927; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- UGT2B11 | c.1584A>G p.R528= | Silent (SNP) | VAF 24/394 reads (6%) | catalogued as rs1458340649; called by muse, mutect2
- ZNF732 | c.9C>A p.L3= | Silent (SNP) | VAF 178/354 reads (50%) | called by muse, mutect2, varscan2
- ADAMTS6 | c.*774G>T | 3'UTR (SNP) | VAF 4/61 reads (7%) | called by muse, mutect2
- CDC5L | c.*3535C>T | 3'UTR (SNP) | VAF 25/44 reads (57%) | called by muse, mutect2, varscan2
- DLGAP1 | c.*2104C>A | 3'UTR (SNP) | VAF 33/146 reads (23%) | called by muse, mutect2, varscan2
- DOCK1 | c.*690A>G | 3'UTR (SNP) | VAF 6/126 reads (5%) | catalogued as rs1317434948; called by muse, mutect2
- FAM169A | c.*1559A>G | 3'UTR (SNP) | VAF 33/170 reads (19%) | called by muse, mutect2, varscan2
- HELLPAR | n.203461C>T | RNA (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- HNF1A | c.1501+214G>T | Intron (SNP) | VAF 27/54 reads (50%) | called by muse, mutect2, varscan2
- KAZN | c.2164-123A>G | Intron (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- LACTB2 | c.286+1398T>C | Intron (SNP) | VAF 25/123 reads (20%) | called by muse, mutect2, varscan2
- LAMP3 | c.*1576T>G | 3'UTR (SNP) | VAF 27/69 reads (39%) | catalogued as rs967205648; called by muse, mutect2, varscan2
- LURAP1 | c.*383A>G | 3'UTR (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- MINK1 | c.1348-89C>G | Intron (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- MLPH | c.*1506T>C | 3'UTR (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- NUDCD2 | c.*250T>A | 3'UTR (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- OCA2 | c.*452A>G | 3'UTR (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2, varscan2
- PXMP2 | c.*65G>A | 3'UTR (SNP) | VAF 139/282 reads (49%) | called by muse, mutect2, varscan2
- RAD50 | c.1793+1241T>C | Intron (SNP) | VAF 71/161 reads (44%) | called by muse, mutect2, varscan2
- RNF222 | c.*1994C>T | 3'UTR (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2, varscan2
- SARDH | c.1020+205G>A | Intron (SNP) | VAF 11/293 reads (4%) | called by muse, mutect2
- SFI1 | c.*161G>A | 3'UTR (SNP) | VAF 16/38 reads (42%) | catalogued as rs15086; called by muse, mutect2, varscan2
- SH2D4B | chr10:80538253 G>C | 5'Flank (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- SNRK | c.*1243A>C | 3'UTR (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- SNX13 | c.*796C>G | 3'UTR (SNP) | VAF 9/118 reads (8%) | called by muse, mutect2
- TEAD1 | c.*3915C>T | 3'UTR (SNP) | VAF 31/115 reads (27%) | called by muse, mutect2, varscan2
- TENT5C | c.*4086_*4112del | 3'UTR (DEL) | VAF 32/69 reads (46%) | called by mutect2, pindel, varscan2
- TMCO4 | c.*632C>T | 3'UTR (SNP) | VAF 8/45 reads (18%) | catalogued as rs1320891818; called by muse, mutect2, varscan2
- TMEM120B | c.*1052A>T | 3'UTR (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- TTLL7 | c.*3484A>G | 3'UTR (SNP) | VAF 46/108 reads (43%) | called by muse, mutect2, varscan2
- UBE2QL1 | c.*3659A>G | 3'UTR (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- WIPF3 | c.1428+398T>A | Intron (SNP) | VAF 65/122 reads (53%) | called by muse, mutect2, varscan2
- ZFPM2 | c.*855A>C | 3'UTR (SNP) | VAF 35/75 reads (47%) | called by muse, mutect2, varscan2
